Somatic mutation profile of tumor specimen HCM-CSHL-0058-C34-86A (aliquot HCM-CSHL-0058-C34-86A-01D-A78L-36) from HCMI case HCM-CSHL-0058-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 82.8 years (30,226 days).
Specimen HCM-CSHL-0058-C34-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7b222b9-0f80-493d-9433-90f5868dd197.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0058-C34-10A (Blood Derived Normal), aliquot HCM-CSHL-0058-C34-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f5957e4-5c52-4fd0-a7c1-33e61d889160

The open-access MAF lists 265 somatic variants for this specimen: 184 protein-altering or splice-affecting, 49 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 49, Nonsense Mutation 17, Intron 14, Splice Site 5, RNA 5, 5'UTR 4, 3'UTR 4, 3'Flank 3, Splice Region 3, 5'Flank 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 64/399 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101201018, COSV67017411; called by muse, mutect2, varscan2
- ADGRA1 | c.838G>T p.G280C | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV101192706; called by muse, mutect2, varscan2
- AKAP9 | c.3599C>T p.S1200F | Missense Mutation (SNP) | VAF 25/341 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV100662192; called by muse, mutect2
- ANK2 | c.10496A>G p.Q3499R | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1415595734; called by muse, mutect2, varscan2
- APC2 | c.3655G>A p.A1219T | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as rs1375738294; called by muse, mutect2, varscan2
- APC2 | c.3656C>G p.A1219G | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs137877386; called by muse, mutect2, varscan2
- AQP9 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.646); catalogued as COSV99582955; called by muse, mutect2
- ASH1L | c.5203G>C p.D1735H | Missense Mutation (SNP) | VAF 23/305 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.443); catalogued as COSV64214833; called by muse, mutect2
- ATP2A2 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs866972164; called by muse, mutect2, varscan2
- AXDND1 | c.1208C>A p.A403D | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100858349; called by muse, mutect2, varscan2
- BAHD1 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV69083781; called by muse, mutect2, varscan2
- BTBD7 | c.2846C>G p.S949* | Nonsense Mutation (SNP) | VAF 35/299 reads (12%) | catalogued as COSV58288247; called by muse, mutect2, varscan2
- CAMSAP1 | c.4217C>G p.S1406C | Missense Mutation (SNP) | VAF 35/335 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56724143; called by muse, mutect2, varscan2
- CCDC178 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV55795365; called by muse, mutect2
- CDC73 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 51/448 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as COSV100813741; called by muse, mutect2, varscan2
- CHRNB2 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 42/413 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs1215936429, COSV63807684; called by muse, mutect2, varscan2
- CLPX | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 13/150 reads (9%) | catalogued as COSV55645261; called by muse, mutect2
- CYTH3 | c.594C>G p.I198M | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100641294; called by muse, mutect2
- DUOX2 | c.3916G>A p.A1306T | Missense Mutation (SNP) | VAF 68/506 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs750364813, COSV66534315; called by muse, mutect2, varscan2
- EHBP1 | c.1511A>G p.N504S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1422306908; called by muse, mutect2, varscan2
- ERFE | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as rs920635226; called by muse, mutect2, varscan2
- FAM186A | c.5972C>T p.S1991L | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1266362236, COSV100525068; called by muse, mutect2, varscan2
- FAM237A | c.128G>A p.S43N | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV69305027; called by muse, mutect2, varscan2
- FSD2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs781225191, COSV58008822; called by muse, mutect2, varscan2
- GBP2 | c.41T>C p.I14T | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs202090771, COSV65070215; called by muse, mutect2, varscan2
- GDF5 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.058); catalogued as rs1309803942; called by muse, mutect2, varscan2
- HS3ST3B1 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1162912862; called by muse, mutect2, varscan2
- IGF2R | c.4799C>T p.S1600F | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV63627867; called by muse, mutect2
- INHBA | c.615G>T p.L205F | Missense Mutation (SNP) | VAF 96/362 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.147); catalogued as COSV54220330, COSV99066567; called by muse, mutect2, varscan2
- IQGAP1 | c.3555G>A p.K1185= | Splice Region (SNP) | VAF 31/261 reads (12%) | catalogued as rs747816026; called by muse, mutect2, varscan2
- ITPR2 | c.1249-2A>G p.X417_splice | Splice Site (SNP) | VAF 15/74 reads (20%) | catalogued as rs1565689068; called by muse, mutect2, varscan2
- KTN1 | c.3523A>G p.I1175V (on ENST00000395314 / NM_001271014.2; = p.I1146V on NM_004986.4) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1010438359; called by muse, mutect2
- MBLAC2 | c.52T>C p.W18R | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57302536; called by muse, mutect2, varscan2
- NCKAP1L | c.3352C>T p.R1118W | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs749025626; called by muse, mutect2, varscan2
- NF2 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 38/326 reads (12%) | catalogued as CM981386, COSV58521244, COSV58525309; called by muse, mutect2, varscan2
- NT5DC4 | c.395C>A p.T132N | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1479236828; called by muse, mutect2
- OR5T3 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs780402245, COSV57381889; called by muse, mutect2
- PCDHA5 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.043); catalogued as rs1170983907, COSV65353712; called by muse, mutect2, varscan2
- PIK3C2A | c.3275G>A p.R1092H | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs138330827; called by muse, mutect2, varscan2
- POT1 | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs758908412; called by muse, mutect2, varscan2
- PREP | c.1729C>G p.R577G (on ENST00000369110; = p.R643G on NM_002726.5) | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64873128; called by muse, mutect2, varscan2
- RANBP6 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs748055944; called by muse, mutect2, varscan2
- RAPGEF6 | c.1303G>C p.V435L | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as rs766859837; called by muse, mutect2
- RBM10 | c.1873G>T p.G625* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as COSV61310019; called by muse, mutect2, varscan2
- RIMS1 | c.2894C>A p.P965Q | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV53471056; called by muse, mutect2, varscan2
- RIMS1 | c.4801G>C p.D1601H | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53452175; called by muse, mutect2, varscan2
- RNF169 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs958478453; called by muse, mutect2, varscan2
- RUVBL2 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99669088; called by muse, varscan2
- SALL4 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53852323; called by muse, mutect2, varscan2
- SLC2A4RG | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.091); catalogued as COSV99829384; called by muse, mutect2, varscan2
- SOGA3 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64106260; called by muse, mutect2, varscan2
- SORCS1 | c.1940+1G>A p.X647_splice | Splice Site (SNP) | VAF 11/133 reads (8%) | catalogued as rs1447669165, COSV53872995; called by muse, mutect2
- SRRM2 | c.3608A>G p.K1203R | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs9921332; called by muse, mutect2, varscan2
- SSU72P8 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV66361273; called by muse, mutect2, varscan2
- TAAR9 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs761234107; called by muse, mutect2
- TAF1A | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV61917808; called by muse, mutect2, varscan2
- TENM3 | c.2407C>A p.Q803K | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs753495814; called by muse, mutect2, varscan2
- TNS1 | c.4636A>G p.N1546D | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.89); catalogued as rs1248701399; called by muse, mutect2, varscan2
- TPO | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 61/467 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.194); catalogued as COSV100222346, COSV61110138; called by muse, mutect2, varscan2
- TPO | c.908C>A p.A303E | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as rs1327228715, COSV61111044; called by muse, mutect2, varscan2
- TPR | c.1460G>C p.R487P | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV66600044; called by muse, mutect2, varscan2
- TRPC7 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV61457307; called by muse, mutect2, varscan2
- UNC45B | c.1261G>C p.G421R | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99269106; called by muse, mutect2
- VWC2 | c.809G>A p.C270Y | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV61487351; called by muse, varscan2
- WDR81 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs1293736314; called by muse, mutect2, varscan2
- WWTR1 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 23/207 reads (11%) | catalogued as COSV62291505; called by muse, mutect2, varscan2
- ZMYND10 | c.327C>A p.H109Q | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51602012; called by muse, mutect2, varscan2
- ZNF232 | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1292671430; called by muse, mutect2, varscan2
- ZNF716 | c.546G>T p.K182N | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV101348735; called by muse, mutect2, varscan2
- ABCA12 | c.1660C>A p.Q554K (on ENST00000272895 / NM_173076.3; = p.Q236K on NM_015657.3) | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGO1 | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKR1C8P | c.176A>T p.Q59L | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AKT2 | c.1264-2A>T p.X422_splice | Splice Site (SNP) | VAF 69/548 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCHE | c.1079A>G p.Y360C | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BICDL2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- BRPF1 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2
- CAPNS2 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 24/158 reads (15%) | called by muse, mutect2, varscan2
- CCDC39 | c.1519A>T p.K507* | Nonsense Mutation (SNP) | VAF 39/276 reads (14%) | called by muse, mutect2, varscan2
- CDX4 | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CNTN2 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- CUX1 | c.4452G>C p.L1484F | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- DDR1 | c.1848del p.G617Afs*36 (on ENST00000324771; = p.G580Afs*36 on NM_001954.4) | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- DENND5B | c.582G>T p.L194F | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DSCAML1 | c.3902A>G p.Y1301C (on ENST00000321322; = p.Y1241C on NM_020693.4) | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DSPP | c.906A>T p.K302N | Missense Mutation (SNP) | VAF 47/314 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGFLAM | c.1433G>C p.R478T | Missense Mutation (SNP) | VAF 33/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELAC1 | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ELK4 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EMSY | c.3161A>T p.Q1054L | Missense Mutation (SNP) | VAF 47/390 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- EPHA5 | c.1865G>C p.G622A | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.659); called by muse, mutect2
- EPPK1 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 24/190 reads (13%) | called by muse, mutect2, varscan2
- EVC | c.2558A>G p.Q853R | Missense Mutation (SNP) | VAF 55/464 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FBN2 | c.8371C>A p.Q2791K | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNDC3B | c.2599C>G p.L867V | Missense Mutation (SNP) | VAF 46/472 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2
- FSIP2 | c.8440C>G p.Q2814E | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- GFRA2 | c.1377G>A p.M459I | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJC2 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 64/588 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRAMD1B | c.1799-1G>A p.X600_splice | Splice Site (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- HECTD2 | c.96G>C p.E32D | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INAVA | c.1841T>G p.V614G | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- IPO11 | c.1175-2A>G p.X392_splice | Splice Site (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- IQGAP1 | c.2839G>C p.D947H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ITPR3 | c.4438T>C p.F1480L | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ITPRIPL1 | c.97A>G p.M33V (on ENST00000439118 / NM_001008949.3; = p.M41V on NM_178495.6) | Missense Mutation (SNP) | VAF 102/369 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KIF2C | c.1211T>C p.I404T | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL2 | c.1072G>C p.V358L | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- LAMA2 | c.7104C>A p.F2368L | Missense Mutation (SNP) | VAF 47/358 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LBP | c.1363C>A p.R455S | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.206); called by muse, mutect2
- LIMD2 | c.42+3A>C | Splice Region (SNP) | VAF 22/99 reads (22%) | called by muse, mutect2, varscan2
- LRCOL1 | c.393C>A p.H131Q | Missense Mutation (SNP) | VAF 17/203 reads (8%) | PolyPhen benign (0.001); called by muse, mutect2
- LYST | c.4913C>T p.S1638L | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- MARCHF11 | c.602T>A p.L201Q | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MED1 | c.3278G>A p.G1093D | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MGA | c.5680G>T p.V1894L (on ENST00000219905 / NM_001164273.1; = p.V1685L on NM_001080541.2) | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MS4A6E | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC16 | c.12407C>T p.T4136I | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MUC17 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- MUC2 | c.1235C>A p.S412Y | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYH11 | c.3988C>A p.Q1330K | Missense Mutation (SNP) | VAF 69/626 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NEUROD2 | c.1064C>A p.S355* | Nonsense Mutation (SNP) | VAF 22/193 reads (11%) | called by muse, mutect2, varscan2
- NKD1 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NPHS1 | c.2975C>A p.P992Q | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NR5A2 | c.1552T>C p.Y518H (on ENST00000367362 / NM_205860.3; = p.Y472H on NM_003822.5) | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); called by muse, varscan2
- NSUN7 | c.1240C>G p.L414V | Missense Mutation (SNP) | VAF 23/285 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- NSUN7 | c.1981T>G p.S661A | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2
- NYNRIN | c.3757G>A p.A1253T | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ODF3B | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 51/397 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OR2H1 | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- OR5H15 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 49/332 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PARM1 | c.847A>T p.R283W | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAX1 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); called by muse, mutect2
- PCDHB6 | c.1302C>G p.S434R | Missense Mutation (SNP) | VAF 49/467 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PCDHGA2 | c.2105G>C p.C702S | Missense Mutation (SNP) | VAF 64/474 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PCSK6 | c.2374G>T p.E792* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- PCYT1A | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 24/363 reads (7%) | called by muse, mutect2
- PER2 | c.3556G>A p.E1186K | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PIP4K2C | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- PLCB1 | c.1495C>G p.P499A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.084); called by muse, mutect2
- PLCB2 | c.1786A>C p.N596H | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLEC | c.5488G>A p.E1830K (on ENST00000322810 / NM_201380.4; = p.E1720K on NM_000445.5) | Missense Mutation (SNP) | VAF 153/471 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- POTEC | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 64/760 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); called by muse, mutect2
- PPP1R12A | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2
- PRDM2 | c.3442G>T p.D1148Y | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PRDM9 | c.1721A>T p.H574L | Missense Mutation (SNP) | VAF 49/686 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RAI1 | c.5539G>T p.E1847* | Nonsense Mutation (SNP) | VAF 50/379 reads (13%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.3421C>G p.L1141V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RASEF | c.482G>C p.R161T | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2
- RHAG | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 37/314 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- RP1L1 | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 63/498 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- SETD5 | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- SHC2 | c.1046dup p.G351Rfs*85 | Frame Shift Ins (INS) | VAF 21/170 reads (12%) | called by mutect2, pindel, varscan2
- SI | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- SLC10A2 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 42/352 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SLC10A3 | c.1249G>T p.V417F | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A6 | c.363C>G p.F121L | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SMARCA4 | c.1680C>A p.Y560* | Nonsense Mutation (SNP) | VAF 50/416 reads (12%) | called by muse, mutect2, varscan2
- SMURF1 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SNX33 | c.1026G>C p.K342N | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTY2D1 | c.1066A>G p.M356V | Missense Mutation (SNP) | VAF 39/409 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- SRCAP | c.5647C>T p.P1883S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYNE1 | c.7589G>T p.W2530L (on ENST00000367255 / NM_182961.4; = p.W2537L on NM_033071.3) | Missense Mutation (SNP) | VAF 25/306 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- TCF7L1 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- TMEM236 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 58/572 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPH2 | c.1217G>T p.C406F | Missense Mutation (SNP) | VAF 44/509 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2
- TREX1 | c.-26-4C>A | Splice Region (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- TRPM1 | c.2610C>A p.S870R | Missense Mutation (SNP) | VAF 53/468 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TSPOAP1 | c.713G>C p.C238S | Missense Mutation (SNP) | VAF 124/430 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UACA | c.900G>T p.E300D | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- UBE2QL1 | c.403A>T p.K135* | Nonsense Mutation (SNP) | VAF 15/202 reads (7%) | called by muse, mutect2
- ULK3 | c.1385C>G p.S462W | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2
- UMPS | c.1214G>T p.R405L | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- WDR70 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WIF1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.044); called by muse, mutect2
- WNK1 | c.4522C>T p.Q1508* (on ENST00000315939 / NM_018979.4; = p.Q1261* on NM_014823.3) | Nonsense Mutation (SNP) | VAF 72/241 reads (30%) | called by muse, mutect2, varscan2
- ZFP14 | c.1456G>T p.G486C | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZFP2 | c.311G>T p.C104F | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZHX3 | c.911G>A p.S304N | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- ZNF620 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 59/488 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, varscan2
- ZNF646 | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 25/274 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2
- ZNF646 | c.2054G>C p.R685T | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZPLD1 | c.306G>T p.E102D (on ENST00000466937 / NM_001329788.1; = p.E118D on NM_175056.2) | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.137); called by muse, mutect2
- ZW10 | c.1810T>G p.L604V | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- A2M | c.3696C>G p.T1232= | Silent (SNP) | VAF 54/321 reads (17%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.3168C>T p.T1056= | Silent (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
- ARMC6 | c.1357C>T p.L453= (on ENST00000392336; = p.L428= on NM_033415.4) | Silent (SNP) | VAF 94/259 reads (36%) | called by muse, mutect2, varscan2
- BEND6 | c.435C>T p.A145= | Silent (SNP) | VAF 20/258 reads (8%) | catalogued as COSV66069512; called by muse, mutect2
- C11orf16 | c.357C>T p.F119= | Silent (SNP) | VAF 27/205 reads (13%) | catalogued as rs756038720; called by muse, mutect2, varscan2
- CADPS | c.657G>A p.V219= | Silent (SNP) | VAF 31/294 reads (11%) | called by muse, mutect2, varscan2
- CAPNS2 | c.312C>G p.L104= | Silent (SNP) | VAF 34/308 reads (11%) | called by muse, mutect2, varscan2
- CHRNB1 | c.85C>A p.R29= | Silent (SNP) | VAF 46/357 reads (13%) | called by muse, mutect2, varscan2
- CTU1 | c.141G>A p.L47= | Silent (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- DCAF8L1 | c.99G>A p.T33= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs1176396699, COSV71595427; called by muse, mutect2, varscan2
- DLGAP3 | c.754C>A p.R252= | Silent (SNP) | VAF 51/229 reads (22%) | called by muse, mutect2, varscan2
- EGR3 | c.339G>T p.V113= | Silent (SNP) | VAF 33/259 reads (13%) | called by muse, mutect2, varscan2
- FAM171A1 | c.726C>A p.V242= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV100968674; called by muse, mutect2
- FBLIM1 | c.255C>T p.C85= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100181850; called by muse, mutect2, varscan2
- FER1L6 | c.1374C>A p.T458= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs527654182; called by muse, varscan2
- FEZ1 | c.853C>A p.R285= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as rs1347208502, COSV54026913; called by muse, mutect2, varscan2
- FOXL1 | c.132C>A p.A44= | Silent (SNP) | VAF 40/394 reads (10%) | called by muse, mutect2
- HAPLN1 | c.507C>G p.R169= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
- KCNG2 | c.123G>A p.A41= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as rs780142518; called by muse, mutect2
- KRT6C | c.1002C>T p.I334= | Silent (SNP) | VAF 189/724 reads (26%) | catalogued as rs369806166; called by muse, mutect2, varscan2
- KRT9 | c.1839C>T p.Y613= | Silent (SNP) | VAF 34/223 reads (15%) | catalogued as rs142173628; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRIT3 | c.517C>T p.L173= | Silent (SNP) | VAF 44/130 reads (34%) | called by muse, mutect2
- MED25 | c.960C>T p.F320= | Silent (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- MYO1F | c.2175G>A p.L725= | Silent (SNP) | VAF 55/495 reads (11%) | called by muse, mutect2, varscan2
- NFKB2 | c.60G>A p.L20= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- NT5DC4 | c.396C>A p.T132= | Silent (SNP) | VAF 30/374 reads (8%) | called by muse, mutect2
- OR5H2 | c.219T>C p.F73= | Silent (SNP) | VAF 20/175 reads (11%) | called by muse, mutect2, varscan2
- PCDHA10 | c.1899G>T p.T633= | Silent (SNP) | VAF 33/222 reads (15%) | catalogued as rs782434773, COSV56477279; called by muse, mutect2, varscan2
- PCDHA11 | c.2121C>A p.S707= | Silent (SNP) | VAF 43/355 reads (12%) | called by muse, mutect2, varscan2
- RAD50 | c.2505A>G p.K835= | Silent (SNP) | VAF 32/372 reads (9%) | catalogued as rs996373843; ClinVar: likely benign; called by muse, mutect2
- REM2 | c.54C>G p.L18= | Silent (SNP) | VAF 22/270 reads (8%) | called by muse, mutect2
- RXFP3 | c.927C>A p.A309= | Silent (SNP) | VAF 46/264 reads (17%) | called by muse, mutect2, varscan2
- SLC35F2 | c.222T>C p.L74= | Silent (SNP) | VAF 48/164 reads (29%) | called by muse, mutect2, varscan2
- SLC38A10 | c.2721G>C p.L907= | Silent (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- SMAD6 | c.570G>A p.T190= | Silent (SNP) | VAF 25/255 reads (10%) | catalogued as rs1338246502; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNX29 | c.1965G>T p.R655= | Silent (SNP) | VAF 38/342 reads (11%) | called by muse, mutect2, varscan2
- SPHKAP | c.3891G>T p.G1297= | Silent (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- SPOCK2 | c.312G>A p.Q104= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV58036528; called by muse, mutect2, varscan2
- ST3GAL5 | c.1074C>A p.L358= (on ENST00000377332; = p.L398= on NM_003896.4) | Silent (SNP) | VAF 28/292 reads (10%) | called by muse, mutect2
- TET1 | c.6162A>T p.L2054= | Silent (SNP) | VAF 87/313 reads (28%) | called by muse, mutect2, varscan2
- TG | c.1959T>A p.G653= | Silent (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- TM7SF2 | c.801G>A p.V267= | Silent (SNP) | VAF 27/238 reads (11%) | called by muse, mutect2, varscan2
- TNFRSF21 | c.1779C>T p.P593= | Silent (SNP) | VAF 27/212 reads (13%) | called by muse, mutect2, varscan2
- TRNP1 | c.249C>T p.L83= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- UGT2B4 | c.840C>A p.L280= | Silent (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- ULK3 | c.1386G>A p.S462= | Silent (SNP) | VAF 20/205 reads (10%) | catalogued as rs770506398, COSV101475573; called by muse, mutect2
- WDR64 | c.2352C>A p.I784= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as rs944206059; called by muse, mutect2, varscan2
- ZNF423 | c.732G>A p.S244= (on ENST00000563137 / NM_001379286.1; = p.S236= on NM_015069.4) | Silent (SNP) | VAF 33/299 reads (11%) | catalogued as rs977567436, COSV52176592, COSV52183945; called by muse, mutect2, varscan2
- ZNF547 | c.423G>T p.P141= | Silent (SNP) | VAF 20/226 reads (9%) | called by muse, mutect2
- ADAD2 | c.419-142G>C | Intron (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- ADGRF3 | chr2:26309091 C>G | 3'Flank (SNP) | VAF 26/215 reads (12%) | catalogued as COSV100275219, COSV61052400; called by muse, mutect2, varscan2
- ADGRV1 | c.*18G>A | 3'UTR (SNP) | VAF 37/350 reads (11%) | catalogued as rs368671859; called by muse, mutect2, varscan2
- ATG4B | c.812-67C>T | Intron (SNP) | VAF 21/222 reads (9%) | catalogued as rs755654689; called by muse, mutect2
- BTNL8 | c.862+9G>A | Intron (SNP) | VAF 67/294 reads (23%) | catalogued as rs368569419; called by muse, mutect2, varscan2
- C19orf12 | chr19:29700174 C>A | 3'Flank (SNP) | VAF 24/165 reads (15%) | called by muse, mutect2, varscan2
- CCDC162P | n.2474T>A | RNA (SNP) | VAF 23/193 reads (12%) | called by muse, varscan2
- CIDEA | c.38+423C>A | Intron (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- DNAH14 | c.1033-4614C>A | Intron (SNP) | VAF 18/282 reads (6%) | catalogued as COSV64788756; called by muse, mutect2
- FBXL15 | c.-864G>A | 5'UTR (SNP) | VAF 16/91 reads (18%) | catalogued as rs1288912805; called by muse, mutect2, varscan2
- HAS1 | chr19:51723978 C>T | 5'Flank (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2, varscan2
- HNF4A | c.*38C>A | 3'UTR (SNP) | VAF 10/82 reads (12%) | catalogued as COSV57384930; called by muse, mutect2, varscan2
- ITGA2B | c.2728-22G>T | Intron (SNP) | VAF 33/300 reads (11%) | called by muse, mutect2, varscan2
- ITGAX | c.862-23G>A | Intron (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- LINC01193 | n.792G>T | RNA (SNP) | VAF 51/1405 reads (4%) | called by muse, mutect2
- MIR1205 | n.36T>G | RNA (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- MS4A6E | c.147+571G>T | Intron (SNP) | VAF 17/88 reads (19%) | catalogued as rs1371150543; called by muse, mutect2, varscan2
- NUDT1 | c.-18G>C | 5'UTR (SNP) | VAF 21/274 reads (8%) | called by muse, mutect2
- OSCAR | c.*400G>T | 3'UTR (SNP) | VAF 27/249 reads (11%) | catalogued as rs765318712; called by muse, mutect2
- PA2G4 | chr12:56104544 C>A | 5'Flank (SNP) | VAF 69/655 reads (11%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157700 A>G | 3'Flank (SNP) | VAF 90/814 reads (11%) | called by muse, mutect2, varscan2
- PKP1 | c.-38C>A | 5'UTR (SNP) | VAF 25/250 reads (10%) | called by muse, mutect2, varscan2
- PMS2 | c.*152C>G | 3'UTR (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2, varscan2
- SCIN | c.200-485G>T | Intron (SNP) | VAF 24/252 reads (10%) | catalogued as rs1475657534; called by muse, mutect2
- SCIN | c.200-484G>T | Intron (SNP) | VAF 24/252 reads (10%) | catalogued as rs1165293304; called by muse, mutect2
- SERPINA3 | c.-8-16G>T | Intron (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- SNORD113-9 | n.70del | RNA (DEL) | VAF 8/75 reads (11%) | called by mutect2, pindel, varscan2
- SRGAP3 | c.1436+40C>T | Intron (SNP) | VAF 25/231 reads (11%) | catalogued as rs925414277; called by muse, mutect2, varscan2
- ST3GAL6 | c.-332G>T | 5'UTR (SNP) | VAF 24/270 reads (9%) | called by muse, mutect2
- TSBP1-AS1 | n.298C>G | RNA (SNP) | VAF 18/76 reads (24%) | called by muse, varscan2
- UGT1A6 | c.862-23334C>T | Intron (SNP) | VAF 63/531 reads (12%) | catalogued as rs373107890; called by muse, mutect2, varscan2
- UGT1A6 | c.862-11982G>A | Intron (SNP) | VAF 42/294 reads (14%) | called by muse, mutect2, varscan2
